Somatic mutation profile of tumor specimen C3L-01862-01 (aliquot CPT0092530009) from CPTAC case C3L-01862, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 81.7 years (29,843 days).
Specimen C3L-01862-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08d76e17-7303-42f3-ae8a-6d94609fc7c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01862-31 (Blood Derived Normal), aliquot CPT0093710002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37020d3e-56b6-49e9-8d0b-3f3abeeae6f1

The open-access MAF lists 185 somatic variants for this specimen: 137 protein-altering or splice-affecting, 29 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 29, Intron 10, Frame Shift Del 7, Nonsense Mutation 6, RNA 3, Splice Site 3, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs120074189, CM157149, CM981131; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 33/147 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- STK11 | c.180C>A p.Y60* | Nonsense Mutation (SNP) | VAF 51/271 reads (19%) | catalogued as rs778376925, CD064644, CM981863, CM991149, COSV58820509, COSV58821737, COSV58821906; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.2056C>T p.R686* (on ENST00000547588 / NM_001122772.2; = p.R350* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | catalogued as rs775039304; called by muse, mutect2, varscan2
- CAD | c.3813G>T p.L1271F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53031563; called by muse, varscan2
- CDK13 | c.2269C>T p.R757W | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs549473641, COSV51703707; called by muse, mutect2, varscan2
- COL6A1 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 44/232 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as rs931928611; called by muse, mutect2, varscan2
- CSMD3 | c.1705G>A p.D569N (on ENST00000297405 / NM_001363185.1; = p.D465N on NM_052900.3) | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV99829795, COSV99846956; called by muse, mutect2, varscan2
- CTTNBP2 | c.4475T>A p.L1492Q | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs974798801; called by muse, mutect2, varscan2
- EP400 | c.7553C>T p.P2518L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs767154660; called by muse, mutect2, varscan2
- EPHA5 | c.2173G>A p.A725T | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV56638005, COSV56662927; called by muse, mutect2, varscan2
- FAM131C | c.613G>C p.D205H | Missense Mutation (SNP) | VAF 34/435 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs1370207463; called by muse, mutect2
- FMN2 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99070471; called by muse, mutect2, varscan2
- FRMPD2 | c.2911A>G p.S971G | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs782126142; called by mutect2, varscan2
- LAMA4 | c.4782G>T p.L1594F (on ENST00000230538 / NM_001105206.3; = p.L1587F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/442 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as COSV57904491; called by muse, mutect2, varscan2
- LYPLAL1 | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100859720; called by muse, mutect2, varscan2
- MMP16 | c.1590G>T p.M530I | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV54194377, COSV99685927; called by muse, mutect2, varscan2
- MUC16 | c.19060A>C p.K6354Q | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1170870245, COSV67453452; called by muse, mutect2, varscan2
- NELL1 | c.2208G>T p.E736D | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV54315526; called by muse, varscan2
- OLFML2B | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as rs750492409, COSV54198425; called by muse, mutect2, varscan2
- OR5T1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143790336; called by muse, mutect2
- PCDHA13 | c.217del p.D73Tfs*5 | Frame Shift Del (DEL) | VAF 59/421 reads (14%) | catalogued as COSV56485794, COSV56496336, COSV99167324; called by mutect2, varscan2
- PCDHA13 | c.734C>G p.S245C | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56494403; called by muse, mutect2, varscan2
- PEG3 | c.2935G>T p.A979S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.596); catalogued as rs1189614029; called by muse, mutect2, varscan2
- PHF24 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.975); catalogued as COSV54273551; called by muse, mutect2, varscan2
- POLD2 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs374486246; called by muse, mutect2, varscan2
- RASGRP4 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs1467408880; called by muse, mutect2, varscan2
- RBFOX3 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 57/367 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1207425560, COSV70553484; called by muse, mutect2, varscan2
- RYR2 | c.5428G>T p.V1810F | Missense Mutation (SNP) | VAF 60/435 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as CM122155, COSV63698234; called by muse, mutect2, varscan2
- SPATA31D1 | c.3509C>A p.S1170* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as COSV61195985; called by muse, mutect2, varscan2
- SRD5A3 | c.830G>C p.W277S | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99948141; called by muse, mutect2, varscan2
- TECPR1 | c.1827G>T p.W609C | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs765230279; called by muse, mutect2, varscan2
- TLR8 | c.1185C>A p.N395K (on ENST00000218032 / NM_138636.5; = p.N413K on NM_016610.4) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs201316478; called by muse, mutect2, varscan2
- TRDV2 | c.91C>A p.P31T | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1468390944; called by muse, mutect2, varscan2
- TTLL5 | c.3103C>T p.R1035W | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1348688599, COSV54039684; called by muse, mutect2, varscan2
- ZNF317 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV56108460, COSV56109765; called by muse, mutect2, varscan2
- ABCA1 | c.1509+1G>T p.X503_splice | Splice Site (SNP) | VAF 74/380 reads (19%) | called by muse, mutect2, varscan2
- ABCA2 | c.5512G>T p.A1838S (on ENST00000614293; = p.A1808S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC097636.1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ADGRB1 | c.1328del p.G443Afs*147 | Frame Shift Del (DEL) | VAF 25/181 reads (14%) | called by mutect2, pindel, varscan2
- ADH7 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALPK3 | c.4036T>C p.C1346R | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF19 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BNC2 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- CCAR2 | c.1201A>T p.K401* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | called by muse, varscan2
- CCDC105 | c.115_117del p.C39del | In Frame Del (DEL) | VAF 43/224 reads (19%) | called by mutect2, pindel*, varscan2*
- CCDC85A | c.1467G>T p.L489F | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- CDH23 | c.4084T>A p.F1362I | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH8 | c.1192C>T p.L398F | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CLEC4G | c.123del p.T42Qfs*6 | Frame Shift Del (DEL) | VAF 37/182 reads (20%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 82/470 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- COL11A1 | c.3440G>T p.G1147V | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL3A1 | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 38/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CPB1 | c.493_494del p.N165* | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | called by mutect2, pindel, varscan2
- CREG1 | c.298A>T p.S100C | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CSF1R | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 40/237 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CWC27 | c.750-1G>T p.X250_splice | Splice Site (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- DPY19L2 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC1I2 | c.1230G>A p.W410* | Nonsense Mutation (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- EFR3A | c.960G>T p.E320D | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- EML6 | c.2750T>C p.V917A | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- EPHA5 | c.1078G>C p.A360P | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.302); called by muse, mutect2
- FOLH1 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAPVD1 | c.3394G>T p.D1132Y (on ENST00000394104; = p.D1141Y on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLYATL2 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GPR155 | c.1847G>C p.S616T | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IFNA8 | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- INSC | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ITGAM | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 57/393 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB1 | c.1463G>T p.W488L | Missense Mutation (SNP) | VAF 34/180 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KEAP1 | c.1626_1629del p.E542Dfs*5 | Frame Shift Del (DEL) | VAF 23/144 reads (16%) | called by mutect2, pindel, varscan2
- KIF5C | c.2746A>T p.R916W | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KLHL1 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- LAMA1 | c.6602G>T p.W2201L | Missense Mutation (SNP) | VAF 58/337 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LINC01193 | n.718C>A | Splice Region (SNP) | VAF 27/225 reads (12%) | called by mutect2, varscan2
- LMLN2 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAGEB17 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCTP1 | c.1710G>T p.Q570H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- MOCOS | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MROH7 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- MROH7 | c.1930C>T p.Q644* | Nonsense Mutation (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- MUC16 | c.11117C>A p.P3706H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MUC16 | c.11116C>A p.P3706T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- MYO1F | c.970C>A p.R324S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYPN | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAV2 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NFRKB | c.1165C>A p.L389M (on ENST00000446488 / NM_001143835.2; = p.L414M on NM_006165.3) | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- NIPBL | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OPTC | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 87/644 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR10C1 | c.165_166insT p.L56Sfs*67 (on ENST00000622521; = p.L54Sfs*67 on NM_013941.3) | Frame Shift Ins (INS) | VAF 42/252 reads (17%) | called by mutect2, pindel*, varscan2
- OR10H3 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, varscan2
- OR14C36 | c.263C>A p.T88N | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PANK4 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- PC | c.1138A>G p.T380A | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PDK2 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PIEZO1 | c.1372A>G p.S458G | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, varscan2
- PTCHD4 | c.1619G>T p.R540I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PTPN11 | c.1584G>T p.R528S | Missense Mutation (SNP) | VAF 80/469 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- RBBP6 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- RGR | c.887G>C p.*296Sext*98 | Nonstop Mutation (SNP) | VAF 58/375 reads (15%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.1088G>T p.C363F (on ENST00000265814 / NM_001198628.1; = p.C336F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR2 | c.10997A>T p.Q3666L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SCN9A | c.5568G>A p.M1856I (on ENST00000303354; = p.M1845I on NM_002977.3) | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SDR9C7 | c.204T>G p.D68E | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- SECISBP2 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 66/357 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC11A1 | c.5del p.T2Kfs*9 | Frame Shift Del (DEL) | VAF 13/110 reads (12%) | called by mutect2, pindel, varscan2
- SLC24A2 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 62/434 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK3 | c.1900G>T p.G634W | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- SMARCA4 | c.211dup p.Q71Pfs*11 | Frame Shift Ins (INS) | VAF 40/220 reads (18%) | called by mutect2, pindel, varscan2
- SNRPF | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA18 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPEN | c.6906del p.G2303Efs*50 | Frame Shift Del (DEL) | VAF 31/203 reads (15%) | called by mutect2, pindel, varscan2
- SPOCK1 | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- STARD9 | c.5195G>T p.W1732L | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SYNE2 | c.14189T>G p.L4730R | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TEAD1 | c.212A>C p.E71A | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- TLL2 | c.2534C>A p.P845H | Missense Mutation (SNP) | VAF 56/336 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TNRC18 | c.4558A>C p.S1520R | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TPCN1 | c.2151A>C p.K717N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- TRBV7-1 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TSGA10IP | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TUBGCP5 | c.2252C>T p.T751I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- UBE3A | c.1617+3_1617+6del | Splice Region (DEL) | VAF 29/253 reads (11%) | called by mutect2, pindel, varscan2
- UGCG | c.180A>C p.K60N | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- USP33 | c.1889G>T p.S630I | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- VCAN | c.4807C>G p.L1603V | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- VN1R5 | c.241G>C p.D81H | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- VPS13B | c.8672T>A p.V2891E | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- VPS37A | c.611T>C p.L204S | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.996); called by muse, varscan2
- VSIR | c.899-1G>T p.X300_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | called by muse, varscan2
- WNK1 | c.1768A>G p.K590E | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- WNT16 | c.410G>C p.R137T (on ENST00000222462 / NM_057168.2; = p.R127T on NM_016087.2) | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZFP57 | c.939G>T p.R313S | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF416 | c.1718C>A p.T573N | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF568 | c.1340A>T p.E447V | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF716 | c.1192C>A p.H398N | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF805 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- AL441992.2 | c.663C>T p.Y221= | Silent (SNP) | VAF 46/233 reads (20%) | called by mutect2, varscan2
- ALOX5 | c.1644C>T p.S548= | Silent (SNP) | VAF 34/216 reads (16%) | catalogued as rs1564452042; called by muse, mutect2, varscan2
- ARSI | c.999G>T p.L333= | Silent (SNP) | VAF 13/92 reads (14%) | called by mutect2, varscan2
- BSN | c.11175C>A p.S3725= | Silent (SNP) | VAF 54/355 reads (15%) | called by muse, mutect2, varscan2
- DMRTA2 | c.33C>A p.P11= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- EXO5 | c.1008C>T p.D336= | Silent (SNP) | VAF 36/330 reads (11%) | catalogued as rs776442201, COSV56416200; called by muse, mutect2, varscan2
- FAM71B | c.1077G>A p.S359= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as rs369213663, COSV57228490; called by muse, mutect2, varscan2
- FAT3 | c.12810G>A p.S4270= | Silent (SNP) | VAF 35/245 reads (14%) | catalogued as rs768838868, COSV53120559; called by muse, mutect2, varscan2
- FITM1 | c.615C>A p.A205= | Silent (SNP) | VAF 31/249 reads (12%) | called by muse, mutect2, varscan2
- GATAD1 | c.735G>A p.E245= | Silent (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- GPR107 | c.960C>T p.S320= | Silent (SNP) | VAF 32/187 reads (17%) | catalogued as rs1369461553; called by muse, mutect2, varscan2
- GPR50 | c.633C>A p.I211= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV54439565; called by muse, mutect2, varscan2
- IL4I1 | c.372C>A p.L124= | Silent (SNP) | VAF 47/194 reads (24%) | catalogued as COSV62009533; called by muse, mutect2, varscan2
- KLHDC8A | c.799C>A p.R267= | Silent (SNP) | VAF 29/410 reads (7%) | catalogued as rs376907601; called by muse, mutect2
- KRT6B | c.46C>A p.R16= | Silent (SNP) | VAF 48/398 reads (12%) | called by muse, mutect2, varscan2
- MAP3K15 | c.3198G>A p.V1066= | Silent (SNP) | VAF 7/72 reads (10%) | called by muse, mutect2
- OR6J1 | c.921T>G p.V307= | Silent (SNP) | VAF 24/204 reads (12%) | called by muse, mutect2
- PCDHGA4 | c.486C>A p.P162= | Silent (SNP) | VAF 25/143 reads (17%) | catalogued as COSV99533913; called by muse, mutect2, varscan2
- PGBD5 | c.822G>T p.G274= (on ENST00000525115; = p.G343= on NM_001258311.2) | Silent (SNP) | VAF 95/238 reads (40%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1542C>T p.I514= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs201964824, COSV67028303; called by muse, mutect2, varscan2
- SDR9C7 | c.142C>A p.R48= | Silent (SNP) | VAF 50/295 reads (17%) | catalogued as COSV99524608; called by muse, varscan2
- TBC1D12 | c.237G>A p.E79= | Silent (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- TRIM49B | c.480G>T p.V160= | Silent (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- TRIM7 | c.1338C>G p.T446= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- TRIM9 | c.600C>A p.P200= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as COSV53614298; called by muse, mutect2, varscan2
- TTLL9 | c.1095G>A p.L365= | Silent (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.82896C>T p.H27632= (on ENST00000591111; = p.H20208= on NM_003319.4) | Silent (SNP) | VAF 100/610 reads (16%) | called by muse, mutect2, varscan2
- ULK1 | c.1170G>T p.V390= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- ZNF684 | c.642C>G p.P214= | Silent (SNP) | VAF 21/129 reads (16%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+531A>T | Intron (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- ACAD8 | chr11:134253558 G>T | 5'Flank (SNP) | VAF 23/133 reads (17%) | called by mutect2, varscan2
- ADARB2 | c.101-177644C>A | Intron (SNP) | VAF 36/270 reads (13%) | called by muse, mutect2, varscan2
- DAO | chr12:108879638 C>A | 5'Flank (SNP) | VAF 27/168 reads (16%) | called by muse, mutect2, varscan2
- EFL1P1 | n.1794G>T | RNA (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- GRP | c.*18A>T | 3'UTR (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- KCNA1 | c.-44C>T | 5'UTR (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- KCNIP4 | c.61+185542C>A | Intron (SNP) | VAF 32/221 reads (14%) | catalogued as COSV101190743; called by muse, mutect2, varscan2
- KHDC1 | c.206+25G>A | Intron (SNP) | VAF 29/178 reads (16%) | catalogued as rs1277145436; called by muse, mutect2, varscan2
- KRT7 | chr12:52252317 C>T | 3'Flank (SNP) | VAF 67/406 reads (17%) | called by muse, mutect2, varscan2
- LHCGR | c.536+1743T>C | Intron (SNP) | VAF 34/191 reads (18%) | called by muse, mutect2, varscan2
- LINC02817 | n.460G>T | RNA (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- NDUFB9 | c.294+11A>C | Intron (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- NUDCD3 | c.509+17037A>G | Intron (SNP) | VAF 49/306 reads (16%) | catalogued as rs368570120; called by muse, mutect2, varscan2
- OR2M1P | n.293C>G | RNA (SNP) | VAF 113/353 reads (32%) | called by muse, mutect2, varscan2
- SGIP1 | c.99+1061C>A | Intron (SNP) | VAF 32/209 reads (15%) | called by muse, mutect2, varscan2
- TNFAIP8 | c.-65G>C | 5'UTR (SNP) | VAF 19/109 reads (17%) | catalogued as rs1367505384; called by muse, mutect2, varscan2
- TRIM33 | c.2061+985G>A | Intron (SNP) | VAF 21/200 reads (11%) | catalogued as rs1195054464; called by muse, mutect2, varscan2
- ZNF816 | c.64-470G>T | Intron (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
